Somatic mutation profile of tumor specimen TCGA-KK-A7B1-01A (aliquot TCGA-KK-A7B1-01A-11D-A32B-08) from TCGA case TCGA-KK-A7B1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.2 years (23,803 days).
Specimen TCGA-KK-A7B1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ad45c89-0635-4c28-8446-d8032b148fee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7B1-11A (Solid Tissue Normal), aliquot TCGA-KK-A7B1-11A-12D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/220d7f5e-0eb4-4c31-8810-909472e22d44

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADAT | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100528728; called by muse, mutect2, varscan2
- ADGRL3 | c.2168G>A p.R723K (on ENST00000506720 / NM_001322402.2; = p.R655K on NM_015236.6) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as COSV101546910; called by muse, mutect2, varscan2
- ALK | c.1930A>G p.I644V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1436899331, COSV101202752; called by muse, mutect2, varscan2
- HEATR6 | c.1239-1G>A p.X413_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99482630; called by muse, mutect2, varscan2
- KRT12 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99289152; called by muse, mutect2, varscan2
- MACF1 | c.1234A>T p.M412L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100486545; called by muse, mutect2, varscan2
- MTMR6 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV101110853; called by muse, mutect2, varscan2
- PHF14 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV101301865; called by muse, mutect2, varscan2
- RPL10A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs11266793, COSV100003606; called by muse, mutect2, varscan2
- RTL3 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369311059, COSV58183086; called by muse, mutect2, varscan2
- SCFD1 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100356603; called by muse, mutect2, varscan2
- SEPTIN4 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.376); catalogued as COSV58728522; called by muse, mutect2
- SLFN5 | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as rs146569957, COSV100249846; called by muse, mutect2, varscan2
- TNFAIP6 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373227124; called by muse, mutect2, varscan2
- USP33 | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100657246, COSV62469389; called by muse, mutect2
- CDH23 | c.5535C>T p.N1845= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs779425775, COSV56457743; ClinVar: likely benign; called by muse, mutect2, varscan2
- JUP | c.1533C>T p.C511= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100159822, COSV60279414; called by muse, mutect2
- MUC3A | c.7143C>T p.T2381= | Silent (SNP) | VAF 63/266 reads (24%) | catalogued as rs1473422880; called by muse, mutect2, varscan2
- RTF1 | c.1686C>T p.Y562= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV67478314; called by muse, mutect2, varscan2
